Gene-level copy-number profile of tumor specimen HCM-BROD-0051-C64-86A from HCMI case HCM-BROD-0051-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.6 years (941 days).
Specimen HCM-BROD-0051-C64-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 23.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8fa04271-bb27-4110-9c28-6f58191c3034.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0051-C64-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/60562a6c-2453-4dc8-bbd1-40948130e1d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,142; copy number 2: 53,176; copy number 3: 2,598.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 286. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
